Somatic mutation profile of tumor specimen TARGET-30-PAKFUY-01A (aliquot TARGET-30-PAKFUY-01A-01W) from TARGET case TARGET-30-PAKFUY, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.3 years (1,194 days).
Specimen TARGET-30-PAKFUY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d04ff77a-9811-4bc1-ba56-8c75130a950f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAKFUY-10A (Blood Derived Normal), aliquot TARGET-30-PAKFUY-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01e6c6db-af5f-40ad-8c65-9eb69031c6a0

The open-access MAF lists 56 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 9, Nonsense Mutation 5, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD8 | c.785C>G p.A262G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV56045284; called by muse, mutect2, varscan2
- AHNAK | c.7033G>T p.E2345* | Nonsense Mutation (SNP) | VAF 43/250 reads (17%) | catalogued as COSV57217160, COSV57224566; called by muse, mutect2, varscan2
- AHNAK | c.5359G>T p.D1787Y | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV57217171; called by muse, mutect2, varscan2
- C1orf198 | c.772G>C p.V258L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV64175666, COSV64176840; called by muse, mutect2, varscan2
- CASS4 | c.525C>G p.D175E | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100824986, COSV64386947, COSV64387084; called by muse, mutect2, varscan2
- CEP95 | c.196C>A p.Q66K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782421504, COSV56749818; called by muse, mutect2, varscan2
- CNR2 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.14); catalogued as rs372203029; called by muse, mutect2, varscan2
- COL5A3 | c.1683G>T p.E561D | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV53411318, COSV53412750; called by muse, mutect2, varscan2
- DLGAP3 | c.923C>A p.S308* | Nonsense Mutation (SNP) | VAF 81/464 reads (17%) | catalogued as COSV52394894; called by muse, mutect2, varscan2
- DSC1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as COSV57146973; called by muse, mutect2, varscan2
- EHD2 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.565); catalogued as COSV54409157; called by muse, mutect2, varscan2
- HAL | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54118468; called by muse, mutect2, varscan2
- ITGA2 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 48/195 reads (25%) | catalogued as COSV56861225, COSV99671484; called by muse, mutect2, varscan2
- ITIH6 | c.2303C>A p.P768Q | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV54490328; called by muse, mutect2, varscan2
- KLHL20 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 69/330 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52942793; called by muse, mutect2, varscan2
- KRTAP5-9 | c.143G>C p.C48S | Missense Mutation (SNP) | VAF 170/492 reads (35%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.013); catalogued as COSV73200208; called by muse, mutect2, varscan2
- LRRK1 | c.6034C>T p.R2012C | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs780306812, COSV99443715; called by muse, mutect2
- MSI2 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 41/578 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1485302383; called by muse, mutect2
- MUC17 | c.5242A>G p.T1748A | Missense Mutation (SNP) | VAF 60/498 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV60291999; called by muse, mutect2, varscan2
- NHLRC1 | c.392G>C p.G131A | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as COSV61481601; called by muse, mutect2, varscan2
- OR6N2 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 89/653 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV104411267, COSV59411832; called by muse, varscan2
- PDIA5 | c.1031C>A p.A344E | Missense Mutation (SNP) | VAF 122/435 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs749249190, COSV60249884; called by muse, mutect2, varscan2
- PEX5 | c.1619A>G p.E540G (on ENST00000420616; = p.E532G on NM_000319.5) | Missense Mutation (SNP) | VAF 106/417 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56955893; called by muse, mutect2, varscan2
- PRIM2 | c.418A>C p.I140L | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV51424771; called by muse, mutect2, varscan2
- RAB5A | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56084826, COSV56086115; called by muse, mutect2, varscan2
- SH3D19 | c.1508T>C p.L503P | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58791236; called by muse, mutect2, varscan2
- SLC41A3 | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV59988725; called by muse, mutect2, varscan2
- SLC4A8 | c.515G>T p.C172F | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV60654167; called by muse, mutect2, varscan2
- SLFN11 | c.2702A>G p.H901R | Missense Mutation (SNP) | VAF 76/523 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as rs745996688, COSV57699220; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.629T>C p.M210T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | PolyPhen benign (0.197); catalogued as COSV52535813; called by muse, mutect2, varscan2
- TAS2R50 | c.317A>C p.Y106S | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67857117; called by muse, mutect2, varscan2
- TIMM9 | c.236C>A p.A79E | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.372); catalogued as rs778415722, COSV53621763; called by muse, mutect2, varscan2
- TTC37 | c.2930A>G p.Q977R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV62455273; called by muse, mutect2, varscan2
- TYK2 | c.1631G>T p.C544F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.171); catalogued as COSV53388329; called by muse, varscan2
- ZNF862 | c.3247G>A p.A1083T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56224442; called by muse, mutect2, varscan2
- ADGRL2 | c.1468C>T p.R490* | Nonsense Mutation (SNP) | VAF 24/293 reads (8%) | called by muse, mutect2
- ATP2B2 | c.1081G>T p.D361Y (on ENST00000352432; = p.D327Y on NM_001683.5) | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- C16orf71 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.075); called by mutect2, varscan2
- CARD6 | c.1759G>T p.A587S | Missense Mutation (SNP) | VAF 29/385 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.091); called by muse, mutect2
- CEMIP | c.2507G>T p.S836I | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CPA5 | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HEATR6 | c.2995C>A p.Q999K | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- PDZD2 | c.3767C>G p.T1256R | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.296); called by muse, mutect2
- SELP | c.2446G>C p.G816R | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TCHP | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.02); called by muse, mutect2
- CD101 | c.1857T>C p.S619= | Silent (SNP) | VAF 24/388 reads (6%) | called by muse, mutect2
- COL7A1 | c.3747G>T p.V1249= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV60396715; called by muse, mutect2, varscan2
- GPR149 | c.1680C>G p.L560= | Silent (SNP) | VAF 70/246 reads (28%) | catalogued as COSV67667876; called by muse, mutect2, varscan2
- HTT | c.2490G>T p.V830= | Silent (SNP) | VAF 48/826 reads (6%) | called by muse, mutect2
- KCNH6 | c.2031G>C p.L677= | Silent (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- NF1 | c.2295C>T p.R765= | Silent (SNP) | VAF 24/512 reads (5%) | called by muse, mutect2
- SLC14A2 | c.1236G>A p.L412= | Silent (SNP) | VAF 74/988 reads (7%) | called by muse, mutect2
- UTRN | c.4260A>G p.L1420= | Silent (SNP) | VAF 44/279 reads (16%) | catalogued as COSV62338127; called by muse, mutect2, varscan2
- VWF | c.5910C>A p.G1970= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV54623985; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7216C>T | Intron (SNP) | VAF 15/215 reads (7%) | called by muse, mutect2
- OR4C3 | c.-59T>A | 5'UTR (SNP) | VAF 97/333 reads (29%) | catalogued as COSV60586930; called by muse, mutect2, varscan2
